TCGA case TCGA-24-1467 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Washington University. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/34f545ab-d420-4dd2-8db4-3159896efd23

Demographics
Sex at birth: female; Race: white; Age at index: 51 years; Vital status: Dead; Days to death: 3,224 days (8.8 years).

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 51.1 years (18,652 days); Year of diagnosis: 1998; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIIC; Tumor grade: G3; Prior treatment: No.
   Pathology details: Lymphatic invasion present: Yes; Residual tumor measurement: 1-10 mm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 6 days; Days to treatment end: 110 days; Number of cycles: 6; Treatment dose: 4,565 mg; Treatment outcome: Treatment Ongoing; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 6 days; Days to treatment end: 110 days; Number of cycles: 6; Treatment dose: 2,650 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Recurrent Disease; Days to treatment start: 1,277 days (3.5 years); Days to treatment end: 1,391 days (3.8 years); Number of cycles: 2; Treatment dose: 1,275 mg; Treatment outcome: Treatment Ongoing; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Initial disease status: Recurrent Disease; Days to treatment start: 1,277 days (3.5 years); Days to treatment end: 1,391 days (3.8 years); Number of cycles: 4; Treatment dose: 400 mg; Treatment outcome: Treatment Ongoing; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Initial disease status: Recurrent Disease; Days to treatment start: 1,277 days (3.5 years); Days to treatment end: 1,391 days (3.8 years); Number of cycles: 6; Treatment dose: 1,780 mg; Treatment outcome: Treatment Ongoing; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Initial disease status: Recurrent Disease; Days to treatment start: 1,804 days (4.9 years); Days to treatment end: 1,909 days (5.2 years); Number of cycles: 6; Treatment dose: 600 mg; Treatment outcome: Treatment Ongoing; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Initial disease status: Recurrent Disease; Days to treatment start: 1,804 days (4.9 years); Days to treatment end: 1,909 days (5.2 years); Number of cycles: 6; Treatment dose: 1,620 mg; Treatment outcome: Treatment Ongoing; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Topotecan; Initial disease status: Recurrent Disease; Days to treatment start: 2,170 days (5.9 years); Days to treatment end: 2,296 days (6.3 years); Number of cycles: 6; Treatment dose: 60 mg; Treatment outcome: Treatment Ongoing; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Vinorelbine Tartrate; Initial disease status: Recurrent Disease; Days to treatment start: 2,170 days (5.9 years); Days to treatment end: 2,296 days (6.3 years); Number of cycles: 6; Treatment dose: 600 mg; Treatment outcome: Treatment Ongoing; Route of administration: Intravenous.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Tamoxifen; Initial disease status: Recurrent Disease; Days to treatment start: 2,363 days (6.5 years); Days to treatment end: 2,458 days (6.7 years); Treatment dose: 20 mg; Treatment outcome: Treatment Ongoing; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pegylated Liposomal Doxorubicin Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 2,476 days (6.8 years); Days to treatment end: 2,531 days (6.9 years); Number of cycles: 3; Treatment dose: 240 mg; Treatment outcome: Treatment Ongoing; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Initial disease status: Progressive Disease; Days to treatment start: 2,561 days (7.0 years); Days to treatment end: 2,737 days (7.5 years); Number of cycles: 8; Treatment dose: 115 mg; Treatment outcome: Treatment Ongoing; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Initial disease status: Progressive Disease; Days to treatment start: 2,561 days (7.0 years); Days to treatment end: 2,737 days (7.5 years); Number of cycles: 8; Treatment dose: 1,350 mg; Treatment outcome: Treatment Ongoing; Route of administration: Intravenous.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Tamoxifen; Initial disease status: Progressive Disease; Days to treatment start: 2,758 days (7.6 years); Treatment dose: 20 mg; Treatment outcome: Treatment Ongoing; Route of administration: Intravenous.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Treatment intent type: Adjuvant; Days to treatment start: 2,819 days (7.7 years); Days to treatment end: 2,889 days (7.9 years); Treatment dose: 3,610 mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide; Initial disease status: Progressive Disease; Days to treatment start: 2,819 days (7.7 years); Days to treatment end: 2,889 days (7.9 years); Treatment dose: 50 mg; Treatment outcome: Treatment Ongoing; Route of administration: Intravenous.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Initial disease status: Progressive Disease; Days to treatment start: 2,989 days (8.2 years); Days to treatment end: 3,059 days (8.4 years); Treatment dose: 8,871 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pegylated Liposomal Doxorubicin Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 2,989 days (8.2 years); Days to treatment end: 3,059 days (8.4 years); Number of cycles: 3; Treatment dose: 240 mg; Treatment outcome: Treatment Ongoing; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Topotecan; Initial disease status: Progressive Disease; Days to treatment start: 3,073 days (8.4 years); Days to treatment end: 3,101 days (8.5 years); Number of cycles: 2; Treatment dose: 21 mg; Treatment outcome: Treatment Ongoing; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 54.5 years (19,905 days); Days to diagnosis: 1,253 days (3.4 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 1,253 days (3.4 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for recurrent disease.

Follow-up (3 entries)
- Day 1,253 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 1,253 days (3.4 years); Evidence of recurrence type: Positive Biomarker(s).
- Days to follow up: 3,224 days (8.8 years); Disease response: With Tumor.
- Progression or recurrence: Yes; Progression or recurrence type: Distant; Evidence of progression type: Positive Biomarker(s); Timepoint: Post Initial Treatment.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-24-1467-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.3; Intermediate dimension: 1.2; Shortest dimension: 0.7.
  Slide TCGA-24-1467-01A-01-BS1: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 19.
  Slide TCGA-24-1467-01A-01-TS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 4.
- Sample TCGA-24-1467-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Anatomic organ subdivision: Right; Method initial path diagnosis: Tumor resection; Lymphovascular invasion indicator: Yes.
- Drug treatment 1: Pharmaceutical therapy drug name: Taxol.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 3, Route of administrations: Route of administration: PO.
- Drug treatment 4: Pharmaceutical therapy drug name: Doxetaxel; Therapy regimen: Progression.
- Drug treatment 5: Pharmaceutical therapy drug name: Doxil; Therapy regimen: Progression.
- Drug treatment 15: Pharmaceutical therapy drug name: Navelbine.
- Drug treatment 16: Pharmaceutical therapy drug name: Cytoxen; Therapy regimen: Progression.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 3,224 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 3,224 days; disease-free interval: event (new tumor event after initially disease-free), 1,253 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,253 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-24-1467-01A-01D-0472-01): tumor purity 0.77, ploidy 3.98, whole-genome doublings 1.
